Somatic mutation profile of tumor specimen 0DSWA2 from CCDI case PBCIWV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 12.1 years (4,408 days).
Specimen 0DSWA2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91bbefca-3f77-4730-a311-18b446cd3bb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSW9L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8032bcd9-cb42-42d9-a0d7-c6d0cdb8a482

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBA1 | c.1507A>G p.R503G | Missense Mutation (SNP) | VAF 31/505 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs755857636, COSV99595875; called by muse, mutect2
- CHRNB2 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 99/427 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872607; called by muse, mutect2, varscan2
- CNGA2 | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 47/498 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61703604; called by muse, mutect2
- DLC1 | c.2942C>T p.P981L (on ENST00000276297 / NM_001348081.2; = p.P544L on NM_006094.5) | Missense Mutation (SNP) | VAF 50/656 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs781401048; called by muse, mutect2
- FAM53B | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 54/596 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs765399560, COSV99785015; called by muse, mutect2
- NXPH1 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 58/858 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV68314553; called by muse, mutect2
- OAS3 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 26/365 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs767964922; called by muse, mutect2
- PSG7 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs370284670; called by muse, mutect2
- RHBDF1 | c.2260G>C p.V754L | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs751523796; called by mutect2, varscan2
- SHANK1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1269493618, COSV53245650; called by muse, mutect2
- AFF4 | c.282C>G p.F94L | Missense Mutation (SNP) | VAF 34/788 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- AMOT | c.1126C>A p.Q376K | Missense Mutation (SNP) | VAF 57/753 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.049); called by muse, mutect2
- AMOT | c.1125T>A p.S375R | Missense Mutation (SNP) | VAF 54/744 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2
- HEXIM2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFNAR2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2
- RASIP1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SLC5A6 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 40/501 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANK1 | c.990G>A p.E330= | Silent (SNP) | VAF 38/423 reads (9%) | called by muse, mutect2
- CDKAL1 | c.645C>G p.L215= | Silent (SNP) | VAF 62/730 reads (8%) | called by muse, mutect2
- HEPHL1 | c.159C>T p.F53= | Silent (SNP) | VAF 34/388 reads (9%) | catalogued as COSV100243350; called by muse, mutect2
- ITGB3 | c.9G>A p.A3= | Silent (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- LYST | c.7017C>T p.L2339= | Silent (SNP) | VAF 53/959 reads (6%) | catalogued as rs201154390, COSV67707602; called by muse, mutect2
- PRICKLE3 | c.270G>A p.S90= | Silent (SNP) | VAF 28/426 reads (7%) | catalogued as COSV54294883; called by muse, mutect2
- ULK1 | c.369G>A p.A123= | Silent (SNP) | VAF 27/253 reads (11%) | catalogued as rs1420187739; called by muse, mutect2, varscan2
- ZDHHC22 | c.618G>A p.Q206= | Silent (SNP) | VAF 40/499 reads (8%) | called by muse, mutect2
- HLA-DMB | c.*6G>A | 3'UTR (SNP) | VAF 21/426 reads (5%) | called by muse, mutect2
- PRSS22 | c.*89G>A | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 34/282 reads (12%) | called by muse, varscan2
